Somatic mutation profile of tumor specimen HCM-CSHL-0625-C18-06A (aliquot HCM-CSHL-0625-C18-06A-11D-A85K-36) from HCMI case HCM-CSHL-0625-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 66.6 years (24,332 days).
Specimen HCM-CSHL-0625-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af9865e1-cc23-43a0-a124-0afc56fcb4fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0625-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0625-C18-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb6d2e98-2217-44d9-945c-c49a43d999df

The open-access MAF lists 190 somatic variants for this specimen: 139 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 45, Nonsense Mutation 10, Intron 3, Frame Shift Del 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1, 5'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.3079G>T p.E1027* | Nonsense Mutation (SNP) | VAF 272/314 reads (87%) | catalogued as rs1569153948, COSV100653229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 194/267 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHCYL1 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 214/279 reads (77%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.687); catalogued as COSV63209218; called by muse, mutect2, varscan2
- APC | c.4480del p.E1494Kfs*13 | Frame Shift Del (DEL) | VAF 120/264 reads (45%) | catalogued as CD108356, COSV57321403, COSV57381675; called by mutect2, pindel, varscan2
- ATRX | c.4909G>T p.E1637* | Nonsense Mutation (SNP) | VAF 228/262 reads (87%) | catalogued as COSV64884492; called by muse, mutect2, varscan2
- CACNA1E | c.6856C>T p.R2286W (on ENST00000367573 / NM_001205293.3; = p.R2243W on NM_000721.4) | Missense Mutation (SNP) | VAF 263/617 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs762766720, COSV62391040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALD1 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 239/525 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375816775, COSV62645239; called by muse, mutect2, varscan2
- CD5L | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 225/542 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879069186, COSV100941033, COSV63821041; called by muse, mutect2, varscan2
- CH25H | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 191/264 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV64092286; called by muse, mutect2, varscan2
- CSMD2 | c.7367G>A p.R2456Q | Missense Mutation (SNP) | VAF 225/302 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs867709818, COSV53952924; called by muse, mutect2, varscan2
- DLEC1 | c.1790A>G p.Y597C | Missense Mutation (SNP) | VAF 219/401 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1393328329; called by muse, mutect2, varscan2
- EFS | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 306/745 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778032789; called by muse, mutect2, varscan2
- EML5 | c.2846G>A p.G949E | Missense Mutation (SNP) | VAF 138/196 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV61350886; called by muse, varscan2
- FCN2 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 148/394 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1157947141; called by muse, varscan2
- FOXN4 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 187/468 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs958198313, COSV54492879; called by muse, varscan2
- FREM2 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 158/509 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61947552; called by muse, mutect2, varscan2
- GASK1B | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 137/223 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs138914646; called by muse, mutect2, varscan2
- GNAS | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 367/2760 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1568925561, COSV58327280; called by muse, mutect2, varscan2
- GPR50 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 413/477 reads (87%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs900102278, COSV54440920, COSV99505940; called by muse, mutect2, varscan2
- GSC | c.759G>T p.L253F | Missense Mutation (SNP) | VAF 154/429 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); catalogued as COSV53077064, COSV53077706; called by muse, mutect2, varscan2
- GSN | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 99/450 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as rs556563870; ClinVar: benign; called by muse, mutect2, varscan2
- HDAC4 | c.981G>A p.T327= | Splice Region (SNP) | VAF 135/333 reads (41%) | catalogued as rs895364750, COSV61864965; called by muse, mutect2, varscan2
- HDX | c.1815G>T p.L605F | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99946623; called by muse, mutect2, varscan2
- IGLV3-1 | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 138/343 reads (40%) | catalogued as rs61731695; called by muse, mutect2, varscan2
- INPP4A | c.2257G>C p.A753P (on ENST00000074304 / NM_001134224.1; = p.A714P on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 218/568 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.269); catalogued as COSV50792793; called by muse, mutect2, varscan2
- IQSEC3 | c.1354G>A p.E452K (on ENST00000538872 / NM_001170738.2; = p.E149K on NM_015232.1) | Missense Mutation (SNP) | VAF 432/758 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1389676284; called by muse, mutect2
- JARID2 | c.1499A>T p.K500M | Missense Mutation (SNP) | VAF 134/745 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV59200448; called by muse, mutect2, varscan2
- KLHL32 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 205/487 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs766818945, COSV65111992; called by muse, mutect2, varscan2
- KRAS | c.204G>T p.R68S | Missense Mutation (SNP) | VAF 202/557 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55640563, COSV55650115; called by muse, mutect2, varscan2
- KRT15 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 137/412 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs780820668; called by muse, mutect2, varscan2
- LAMA2 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 196/456 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752648056; called by muse, mutect2, varscan2
- LAYN | c.537G>T p.K179N (on ENST00000375615 / NM_001258390.1; = p.K171N on NM_178834.5) | Missense Mutation (SNP) | VAF 188/242 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65105162; called by muse, mutect2, varscan2
- MANSC1 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 118/793 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.068); catalogued as rs138511907; called by muse, mutect2, varscan2
- MAP1S | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 413/952 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs376985455; called by muse, mutect2, varscan2
- MICALL2 | c.1051G>C p.A351P | Missense Mutation (SNP) | VAF 313/761 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1408966509; called by muse, mutect2, varscan2
- MRAP | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 255/527 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.269); catalogued as rs763168814; called by muse, mutect2, varscan2
- NCAM2 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 188/395 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV53105151; called by muse, mutect2, varscan2
- NFS1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 179/1239 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs201504973; called by muse, mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 76/336 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, varscan2
- PAPPA2 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 261/673 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs771214241, COSV62780032; called by muse, mutect2, varscan2
- PCDHA1 | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 206/624 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.611); catalogued as rs1554118055, COSV65372632; called by muse, mutect2, varscan2
- PCDHA12 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 242/644 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV56542763; called by muse, mutect2, varscan2
- PCDHB3 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 242/672 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV50565386; called by muse, mutect2, varscan2
- PDZD2 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 171/748 reads (23%) | catalogued as rs766389561, COSV56856603; called by muse, mutect2, varscan2
- PHLPP2 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 138/354 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.635); catalogued as rs746313254, COSV100673437; called by muse, mutect2, varscan2
- PIDD1 | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 169/468 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs769334697, COSV57192316; called by muse, mutect2, varscan2
- PLIN5 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 420/837 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs751980899, COSV101113716; called by muse, mutect2, varscan2
- PRSS35 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 271/669 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs1367084252; called by muse, mutect2, varscan2
- R3HDML | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 331/1920 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs767349391; called by muse, varscan2
- REV3L | c.2094C>G p.N698K | Missense Mutation (SNP) | VAF 109/163 reads (67%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV62615617; called by muse, mutect2, varscan2
- RFTN2 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 260/605 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371736434; called by muse, mutect2, varscan2
- RYR2 | c.606C>A p.H202Q | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.613); catalogued as rs1438256315, COSV63691206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.7105G>A p.D2369N (on ENST00000389232; = p.D2370N on NM_001036.6) | Missense Mutation (SNP) | VAF 245/346 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754277171; called by muse, mutect2, varscan2
- S1PR3 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 141/697 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.049); catalogued as rs755867055, COSV63980331, COSV63980777; called by muse, mutect2, varscan2
- SAMD9 | c.2557G>A p.V853I | Missense Mutation (SNP) | VAF 164/401 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs534758372, COSV101180317, COSV66078012; called by muse, mutect2, varscan2
- SEC14L5 | c.1714C>A p.Q572K | Missense Mutation (SNP) | VAF 224/565 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs902793015; called by muse, mutect2, varscan2
- SGK1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 170/423 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1041694995; called by muse, mutect2, varscan2
- SLC8A3 | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 260/363 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as COSV63527685; called by muse, mutect2, varscan2
- SMAD4 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 282/372 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61688949; called by muse, mutect2, varscan2
- SMAD6 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 293/379 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV56593281; called by muse, mutect2, varscan2
- SPG7 | c.2314G>A p.E772K (on ENST00000268704; = p.E779K on NM_003119.4) | Missense Mutation (SNP) | VAF 202/524 reads (39%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.502); catalogued as rs755429163; called by muse, mutect2, varscan2
- SRCIN1 | c.2564C>T p.T855M (on ENST00000621492; = p.T821M on NM_025248.3) | Missense Mutation (SNP) | VAF 176/517 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs568302959; called by muse, mutect2, varscan2
- SREBF2 | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 177/413 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs749042683; called by muse, mutect2, varscan2
- SSU72P3 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 256/874 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1385805815; called by muse, mutect2, varscan2
- TG | c.6380G>A p.R2127Q | Missense Mutation (SNP) | VAF 173/335 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs749862463, COSV55070257; called by muse, mutect2, varscan2
- THBS2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 331/729 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759210002, COSV64677175; called by muse, mutect2, varscan2
- TMTC4 | c.60C>G p.F20L (on ENST00000376234 / NM_001350577.2; = p.F39L on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 254/502 reads (51%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60893910; called by muse, mutect2, varscan2
- TNFSF14 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 336/941 reads (36%) | catalogued as rs1314864954, COSV55591351; called by muse, mutect2, varscan2
- TRPS1 | c.2411C>T p.P804L (on ENST00000220888 / NM_001330599.2; = p.P817L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/536 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); catalogued as COSV55235159; called by muse, mutect2, varscan2
- ZIC3 | c.765G>T p.W255C | Missense Mutation (SNP) | VAF 372/431 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54975701; called by mutect2, varscan2
- ZNF208 | c.2828A>C p.K943T | Missense Mutation (SNP) | VAF 177/439 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV68100536; called by muse, mutect2, varscan2
- ZNF219 | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 22/883 reads (2%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV53879048; called by muse, mutect2
- ZNF500 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 320/792 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs991739831; called by muse, mutect2, varscan2
- ZNF506 | c.1248G>C p.K416N | Missense Mutation (SNP) | VAF 144/323 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV101475663; called by muse, mutect2, varscan2
- ZNF816 | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 136/362 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1383822909; called by muse, mutect2, varscan2
- ACP7 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 221/536 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ADHFE1 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 95/361 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- AGBL4 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 187/237 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AKAP13 | c.1571C>G p.T524R | Missense Mutation (SNP) | VAF 455/542 reads (84%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- AL358113.1 | c.343T>G p.L115V | Missense Mutation (SNP) | VAF 179/465 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); called by muse, mutect2
- BHLHE22 | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 142/613 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, varscan2
- BTBD7 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 284/651 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C1QTNF1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 176/424 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CAVIN2 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 206/519 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD109 | c.1340T>G p.F447C | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CFAP92 | c.435C>G p.F145L | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLASRP | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 152/380 reads (40%) | called by muse, mutect2, varscan2
- DNAH1 | c.2001C>G p.S667R | Missense Mutation (SNP) | VAF 202/344 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPP10 | c.2063C>G p.S688C | Missense Mutation (SNP) | VAF 133/332 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- EDEM1 | c.1276T>G p.F426V | Missense Mutation (SNP) | VAF 192/357 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EFCAB3 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 184/446 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF2B5 | c.1604G>T p.S535I (on ENST00000647909; = p.S527I on NM_003907.3) | Missense Mutation (SNP) | VAF 181/371 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- EPHA6 | c.1636G>C p.D546H | Missense Mutation (SNP) | VAF 207/354 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESS2 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 267/594 reads (45%) | called by muse, mutect2, varscan2
- FAM205C | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 219/522 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FBXO48 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 163/429 reads (38%) | called by muse, mutect2, varscan2
- FXR2 | c.1802C>G p.S601C | Missense Mutation (SNP) | VAF 233/316 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- GDF9 | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 17/483 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.343); called by muse, mutect2
- GOLGA6L22 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 241/365 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- GRIK1 | c.2829G>T p.Q943H (on ENST00000327783 / NM_001330994.2; = p.Q899H on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 160/277 reads (58%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- H2AC11 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 486/562 reads (86%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, varscan2
- HDAC1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, mutect2
- HMGCR | c.393G>C p.L131F | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IBTK | c.2524G>C p.D842H | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- INTS8 | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2
- ITGA2 | c.944T>G p.L315* | Nonsense Mutation (SNP) | VAF 41/155 reads (26%) | called by muse, mutect2, varscan2
- ITGB4 | c.3223C>G p.Q1075E | Missense Mutation (SNP) | VAF 260/721 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IZUMO1 | c.403T>G p.C135G | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- JMJD7-PLA2G4B | c.2630G>T p.G877V | Missense Mutation (SNP) | VAF 160/217 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KLC1 | c.147G>T p.L49F | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- LECT2 | c.406dup p.H136Pfs*5 | Frame Shift Ins (INS) | VAF 103/312 reads (33%) | called by mutect2, pindel, varscan2
- LONRF2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- LRP2 | c.1618A>T p.R540W | Missense Mutation (SNP) | VAF 231/613 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYG2 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 19/582 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2
- MEP1A | c.1784-1G>C p.X595_splice | Splice Site (SNP) | VAF 64/294 reads (22%) | called by muse, mutect2, varscan2
- MID1IP1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- MINDY3 | c.94+1G>A p.X32_splice | Splice Site (SNP) | VAF 153/228 reads (67%) | called by muse, mutect2, varscan2
- MINK1 | c.3968C>A p.T1323N | Missense Mutation (SNP) | VAF 235/326 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- MYH2 | c.4354C>G p.Q1452E | Missense Mutation (SNP) | VAF 153/211 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEU3 | c.954T>A p.S318R | Missense Mutation (SNP) | VAF 290/605 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NLRP7 | c.1390T>C p.Y464H | Missense Mutation (SNP) | VAF 101/991 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PARP15 | c.1121T>G p.I374R (on ENST00000464300 / NM_001113523.3; = p.I140R on NM_152615.2) | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- POU4F3 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 159/862 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PSG7 | c.1062C>A p.C354* | Nonsense Mutation (SNP) | VAF 18/576 reads (3%) | called by muse, mutect2
- RNF19B | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 12/361 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.172); called by muse, mutect2
- TCOF1 | c.4132del p.S1378Pfs*197 (on ENST00000377797 / NM_001135243.1; = p.S1301Pfs*197 on NM_000356.4) | Frame Shift Del (DEL) | VAF 295/687 reads (43%) | called by pindel, varscan2
- TENM1 | c.1937G>C p.C646S | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- THBS2 | c.3316G>T p.D1106Y | Missense Mutation (SNP) | VAF 77/489 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TICAM1 | c.2006C>A p.A669E | Missense Mutation (SNP) | VAF 351/926 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- TRAPPC12 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 318/411 reads (77%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIP6 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 189/479 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.17030C>T p.T5677I (on ENST00000591111; = p.T4750I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/335 reads (15%) | PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- UGGT1 | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- VEPH1 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 83/406 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- WIZ | c.963C>A p.S321R | Missense Mutation (SNP) | VAF 167/731 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- XIRP2 | c.8897T>A p.L2966H (on ENST00000628543; = p.L3141H on NM_152381.6) | Missense Mutation (SNP) | VAF 270/605 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ZBTB41 | c.1729T>A p.C577S | Missense Mutation (SNP) | VAF 163/409 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF793 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 113/589 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804A | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 179/429 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- A3GALT2 | c.495C>T p.R165= | Silent (SNP) | VAF 241/323 reads (75%) | called by muse, mutect2, varscan2
- ADCY5 | c.3165C>T p.R1055= | Silent (SNP) | VAF 230/454 reads (51%) | catalogued as rs752267672; called by muse, mutect2, varscan2
- BEST2 | c.510G>A p.K170= | Silent (SNP) | VAF 229/526 reads (44%) | called by muse, mutect2, varscan2
- CCDC102B | c.921A>G p.P307= | Silent (SNP) | VAF 114/169 reads (67%) | called by muse, mutect2, varscan2
- CDRT15L2 | c.279C>T p.Y93= | Silent (SNP) | VAF 127/269 reads (47%) | catalogued as rs1055329969; called by muse, mutect2, varscan2
- CSMD1 | c.10446C>T p.H3482= (on ENST00000520002; = p.H3481= on NM_033225.6) | Silent (SNP) | VAF 106/178 reads (60%) | catalogued as rs778517811; called by muse, mutect2, varscan2
- CTCFL | c.1932C>G p.V644= | Silent (SNP) | VAF 193/1517 reads (13%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.762C>A p.P254= | Silent (SNP) | VAF 445/510 reads (87%) | called by muse, mutect2, varscan2
- DENND2B | c.621C>G p.P207= | Silent (SNP) | VAF 295/763 reads (39%) | called by muse, mutect2, varscan2
- DGKD | c.2130C>T p.D710= (on ENST00000264057 / NM_152879.3; = p.D666= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 232/648 reads (36%) | catalogued as rs747461841, COSV51081587; called by muse, mutect2, varscan2
- DRD5 | c.855C>T p.R285= | Silent (SNP) | VAF 243/447 reads (54%) | catalogued as rs201697048, COSV58577368; called by muse, mutect2, varscan2
- ELOA2 | c.1080C>T p.S360= | Silent (SNP) | VAF 209/270 reads (77%) | catalogued as COSV55294848; called by muse, mutect2, varscan2
- FKBP9 | c.1656G>A p.K552= | Silent (SNP) | VAF 235/655 reads (36%) | called by muse, mutect2, varscan2
- FREM2 | c.4719C>A p.T1573= | Silent (SNP) | VAF 121/451 reads (27%) | called by muse, mutect2, varscan2
- H2AC11 | c.213C>T p.A71= | Silent (SNP) | VAF 495/571 reads (87%) | catalogued as rs773383414; called by muse, varscan2
- HHIPL1 | c.318G>A p.T106= | Silent (SNP) | VAF 292/630 reads (46%) | catalogued as rs541490286, COSV58092492; called by muse, mutect2, varscan2
- IL18 | c.393A>T p.T131= | Silent (SNP) | VAF 107/129 reads (83%) | called by muse, mutect2, varscan2
- ITGA4 | c.2757G>T p.L919= | Silent (SNP) | VAF 118/316 reads (37%) | called by muse, mutect2, varscan2
- KIAA1109 | c.13839A>G p.S4613= | Silent (SNP) | VAF 123/224 reads (55%) | catalogued as COSV52689788; called by muse, mutect2, varscan2
- LDLRAD3 | c.966G>A p.G322= | Silent (SNP) | VAF 367/908 reads (40%) | catalogued as rs750264934; called by muse, mutect2, varscan2
- MUC17 | c.2700T>A p.T900= | Silent (SNP) | VAF 25/817 reads (3%) | called by muse, mutect2
- NIPBL | c.4947A>G p.Q1649= | Silent (SNP) | VAF 70/348 reads (20%) | catalogued as rs1424683975; called by muse, mutect2, varscan2
- OR5D16 | c.789A>C p.V263= | Silent (SNP) | VAF 229/589 reads (39%) | catalogued as COSV65723099; called by muse, mutect2, varscan2
- PAX7 | c.1035C>T p.A345= | Silent (SNP) | VAF 408/548 reads (74%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1785C>T p.R595= | Silent (SNP) | VAF 156/390 reads (40%) | catalogued as COSV56496982; called by muse, mutect2, varscan2
- PCDHGA12 | c.1560C>T p.F520= | Silent (SNP) | VAF 171/405 reads (42%) | catalogued as COSV52770644; called by muse, mutect2, varscan2
- PDE6B | c.1827G>A p.Q609= | Silent (SNP) | VAF 79/380 reads (21%) | catalogued as rs748138553; called by muse, mutect2, varscan2
- PER2 | c.3237C>T p.S1079= | Silent (SNP) | VAF 300/681 reads (44%) | catalogued as rs765956250, COSV54522379; called by muse, mutect2, varscan2
- PLXNB2 | c.2940C>G p.R980= | Silent (SNP) | VAF 353/762 reads (46%) | catalogued as rs189387400; called by muse, mutect2, varscan2
- PRKRA | c.699C>G p.L233= | Silent (SNP) | VAF 178/427 reads (42%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.708C>T p.P236= | Silent (SNP) | VAF 180/287 reads (63%) | catalogued as COSV52570777; called by muse, mutect2, varscan2
- RNF149 | c.984G>A p.E328= | Silent (SNP) | VAF 16/492 reads (3%) | called by muse, mutect2
- SCN7A | c.2115T>C p.C705= | Silent (SNP) | VAF 250/611 reads (41%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.2691G>T p.V897= | Silent (SNP) | VAF 284/643 reads (44%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1530G>T p.L510= | Silent (SNP) | VAF 221/506 reads (44%) | catalogued as COSV99693884; called by muse, varscan2
- SLC22A13 | c.318G>A p.T106= | Silent (SNP) | VAF 129/489 reads (26%) | catalogued as rs753981089, COSV61291469; called by muse, mutect2, varscan2
- TRPC6 | c.69G>A p.A23= | Silent (SNP) | VAF 400/508 reads (79%) | catalogued as rs895758434; called by muse, mutect2, varscan2
- TTN | c.13191C>A p.G4397= (on ENST00000591111; = p.G4351= on NM_003319.4) | Silent (SNP) | VAF 229/549 reads (42%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.1149C>G p.A383= | Silent (SNP) | VAF 233/319 reads (73%) | catalogued as rs1344092595; called by muse, mutect2, varscan2
- UBR1 | c.60G>A p.Q20= | Silent (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- VAT1L | c.450G>A p.P150= | Silent (SNP) | VAF 272/632 reads (43%) | catalogued as rs369885557; called by muse, mutect2, varscan2
- VCAN | c.9300C>T p.N3100= | Silent (SNP) | VAF 369/465 reads (79%) | catalogued as rs764970307, COSV54118279; called by muse, mutect2, varscan2
- WBP11 | c.759T>C p.S253= | Silent (SNP) | VAF 53/531 reads (10%) | called by muse, mutect2, varscan2
- ZBTB7A | c.297C>G p.V99= | Silent (SNP) | VAF 138/907 reads (15%) | called by muse, mutect2, varscan2
- ZNF517 | c.1153C>T p.L385= | Silent (SNP) | VAF 179/647 reads (28%) | called by muse, mutect2, varscan2
- CUL7 | c.-151C>T | 5'UTR (SNP) | VAF 313/776 reads (40%) | catalogued as rs940293699; called by muse, mutect2, varscan2
- IGFN1 | c.1242-66C>G | Intron (SNP) | VAF 269/654 reads (41%) | called by mutect2, varscan2
- NGLY1 | c.1004-200A>T | Intron (SNP) | VAF 48/181 reads (27%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31640273 C>T | 5'Flank (SNP) | VAF 77/322 reads (24%) | called by muse, mutect2, varscan2
- UNC13B | c.761+6097C>T | Intron (SNP) | VAF 123/306 reads (40%) | called by muse, mutect2, varscan2
- ZFP14 | chr19:36331637 G>A | 3'Flank (SNP) | VAF 268/649 reads (41%) | called by muse, mutect2, varscan2
